Surgical pathology report (de-identified scan), CDDP_EAGLE case CDDP-ABIW, project CDDP_EAGLE-1 (CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2)), specimen CDDP-ABIW-TTP1-A (Primary Tumor).

SPECIMEN(S) RECEIVED:

- A) Right lung, upper lobe and superior arch of ribs III-IV, resection
- B) Lymph node from lobar hilus, resection
- C) Paratracheal lymph node, resection

GROSS EXAMINATION:

- A) Surgical resection comprising a lobe of lung measuring 14x9x4 cm in size and two rib segments measuring 13 cm in size. Subpleurally, located at 3 cm and 4 cm from the lateral costal margins of resection, there is a parenchymal neoplasia measuring 5x4.5x2.8 cm, focally necrotic, grayish, and hard, extending to the parietal pleura, to the intercostal soft tissues, and to the bony tissue of the ribs. The pericostal soft tissue and the bony and peribronchial margins of resection are free of tumor. Remainder of lung parenchyma appears congested and emphysematous. Five lymph nodes isolated from hilus.
- B) Three lymph nodes measuring between 2.5 cm and 0.6 cm in greatest diameter.
- C) Several fragments of adipose tissue, from which five lymph nodes isolated.

DIAGNOSIS:

- A, B) Adenocarcinoma of the lung, poorly differentiated (G3), with areas of large-cell undifferentiated carcinoma and squamous metaplasia, infiltrating ribs III and IV and with lymph node and perinodal metastases in 2 of 5 hilar lymph nodes (A7) and 2 of 3 lymph nodes from the lobar hilus (B1-3). Bronchial and costal margins free of tumor.
- C) Chronic reactive lymph node inflammation, 5/5 paratracheal lymph nodes.

TNM staging: pT3 pN1

Histochemical analysis performed: TTF1 -

ICD-0-3

adenocarcinoma, NOS 8140/3
Site: Lung, (R) upper lobe C34.1

ICD-10

C34.11

hw
2/9/16

ICD-10 Discrepancy		☒
Diagnosed Synchronous Primary Tumor		☒

Source: NCI Genomic Data Commons file 89a5cccc-ee3e-4a24-87a0-586451cf8c8e (CDDP-ABIW-TTP1.32B00D8A-DFAE-4B70-A8BE-2C2AB590265D.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).